Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7235, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7235-01A (Primary Tumor).

[page 1 of 5]
******* MODIFIED REPORT - REVIEW ADDENDUM SECTION *********DIAGNOSIS**

- (A) RIGHT MENTAL NERVE BIOPSY:
Peripheral nerve, no tumor present.
- (B) LEFT MENTAL NERVE BIOPSY:
Peripheral nerve, no tumor present.
- (C) RIGHT POSTERIOR BUCCAL MARGIN:
SQUAMOUS CELL CARCINOMA IN SITU.
- (D) RIGHT ANTERIOR BUCCAL MARGIN:
ULCERATED SQUAMOUS MUCOSA, NO TUMOR PRESENT.
- (E) LEFT ANTERIOR LIP MARGIN:
Squamous mucosa, no tumor present.
- (F) LEFT CHEEK MARGIN:
Squamous mucosa, no tumor present.
- (G) RIGHT ANTERIOR LIP MARGIN:
SQUAMOUS CELL CARCINOMA IN SITU.
- (H) RIGHT NECK DISSECTION:
Level IIB - nine lymph nodes negative for tumor (0/9).
Level III - four lymph nodes, negative for tumor (0/4).
Level IV - twelve lymph nodes, negative for tumor (0/12).
- (I) LEFT NECK DISSECTION:
Level I - benign submandibular gland.
Level II - two lymph nodes, negative for tumor (0/2).
Level III - eighteen lymph nodes, negative for tumor (0/18).
Level IV - twelve lymph nodes, negative for tumor (0/12).
- (J) CENTRAL COMPARTMENT DISSECTION:
One lymph node, negative for tumor (0/1).
Benign fibroadipose tissues.
- (K) PROXIMAL V3 RIGHT:
Peripheral nerve, no tumor present.
- (L) RIGHT MANDIBULAR MARGIN, TOUCH PREP:
Benign marrow elements.
- (M) LEFT MANDIBLE MARGIN, TOUCH PREP:
Benign marrow elements.
- (N) RIGHT TONGUE MARGIN:
SQUAMOUS CARCINOMA IN SITU.
- (O) LEFT TONGUE MARGIN:
SQUAMOUS CARCINOMA IN SITU.
- (P) LEFT BASE OF TONGUE:
SQUAMOUS CARCINOMA IN SITU.
- (Q) RIGHT BASE OF TONGUE:
SQUAMOUS CARCINOMA IN SITU.

[page 2 of 5]
cc:

(R) LEFT LEVEL II "B":

Three lymph nodes, negative for tumor (0/3).

(S) COMPOSITE RESECTION, ANTERIOR FLOOR OF MOUTH, MANDIBLE:

INVASIVE POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA WITH BASALOID FEATURES, MAXIMUM DEPTH OF INVASION 9.0 MM.

MAXIMUM TUMOR DIMENSIONS 2.0 CM.

FOCAL LYMPHOVASCULAR INVASION PRESENT.

No perineural invasion identified.

ADJACENT SQUAMOUS CELL CARCINOMA IN SITU.

SOFT TISSUE METASTASIS IDENTIFIED IN MINOR SALIVARY GLAND.

Eight local regional lymph nodes negative for tumor (0/8).

Bony sections pending decalcification.

(T) RIGHT NECK CONTENTS, LEVEL IV:

Eight lymph nodes, negative for tumor (0/8).

(U) EXTRACTED TEETH:

Gross examination only.

GROSS DESCRIPTION

(A) RIGHT MENTAL NERVE BIOPSY - Two tan-red tissue fragments measuring 0.3 x 0.2 x 0.2 cm in aggregate. Submitted in toto for frozen section in A. [REDACTED]

*FS/DX: PERIPHERAL NERVE, NO TUMOR PRESENT. [REDACTED]

(B) LEFT MENTAL NERVE BIOPSY - A 0.8 x 0.2 x 0.2 cm tan-pink tissue fragment. Submitted in toto for frozen section in B. [REDACTED]

*FS/DX: PERIPHERAL NERVE, NO TUMOR PRESENT. [REDACTED]

(C) RIGHT POSTERIOR BUCCAL MARGIN - Received is a tan-pink mucosa covered piece of soft tissue (2.5 x 0.5 x 0.3 cm). The specimen is submitted entirely in C for frozen section. [REDACTED]

*FS/DX: SQUAMOUS CARCINOMA IN SITU. [REDACTED]

(D) RIGHT ANTERIOR BUCCAL MARGIN - Received is a tan-pink mucosa covered piece of soft tissue (2.5 x 0.6 x 0.4 cm). The specimen is submitted entirely for frozen section in D. [REDACTED]

*FS/DX: ULCERATED SQUAMOUS MUCOSA, NO TUMOR PRESENT. [REDACTED]

(E) LEFT ANTERIOR LIP MARGIN - Received is a tan-pink mucosa covered piece of soft tissue (4.0 x 0.3 x 0.2 cm). The specimen is bisected and submitted entirely for frozen section in E. [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(F) LEFT CHEEK MARGIN - Received is a tan-pink mucosa covered piece of soft tissue (2.0 x 0.3 x 0.3 cm). The specimen is submitted entirely for frozen section in F. [REDACTED]

[page 3 of 5]
*FS/DX: NO TUMOR PRESENT. [REDACTED]

(G) RIGHT ANTERIOR LIP MARGIN - Received is a tan-pink mucosa covered piece of soft tissue (4.0x 0.3 x 0.3 cm). The specimen is bisected and submitted entirely for frozen section in G. [REDACTED]

*FS/DX: SQUAMOUS CARCINOMA IN SITU. [REDACTED]

(H) RIGHT NECK DISSECTION - Received is an irregular piece of fibroadipose tissue (12.2 x 7.0 x 1.9 cm). The specimen is divided by the surgeon into levels II "A", II "B", III and IV.

No lymph nodes are identified in level II "A".

Eleven possible lymph nodes are identified in level II "B" (ranging from 0.2 to 3.5 cm in greatest dimension).

Three possible lymph nodes are identified in level III (ranging from 0.2 to 0.6 cm in greatest dimension).

Thirteen possible lymph nodes are identified in level IV (ranging from 0.2 to 1.2 cm in greatest dimension).

SECTION CODE: Level II "B" (H1-H6): H1, five possible lymph nodes; H2, three possible lymph nodes; H3, one lymph node bisected; H4, one lymph node bisected; H5, H6, one lymph node serially sectioned; Level III (H7-H8): H7, two lymph nodes; H8, one lymph node bisected; Level IV (H9-H14): H9, three possible lymph nodes; H10, three possible lymph nodes; H11, one lymph node bisected; H12, two possible lymph nodes; H13, one lymph node bisected; H14, three possible lymph nodes. [REDACTED]

(I) LEFT NECK DISSECTION - Received is an irregular piece of fibroadipose tissue (8.7 x 8.5 x 0.7 cm). The specimen is previously divided into levels I, II, III and IV by the surgeon.

An unremarkable submandibular gland is identified in level I (4.0 x 2.7 x 1.1 cm). No lymph nodes identified in level I.

Four possible lymph nodes are identified in level II (ranging from 0.2 to 0.6 cm in greatest dimension).

Nineteen possible lymph nodes are identified in level III (ranging from 0.2 to 1.2 cm in greatest dimension).

Fourteen possible lymph nodes are identified within level IV (ranging from 0.2 to 1.0 cm in greatest dimension).

SECTION CODE: Level I: I1, submandibular gland; level II (I2, I3): I2, three possible lymph nodes; I3, one possible lymph node; level III (I4-I11): I4-I6, four possible lymph nodes each; I7, three possible lymph nodes; I8, one possible lymph node bisected; I9, one possible lymph node bisected; I10, one possible lymph node bisected; I11, one lymph node trisected; level IV (I12-I16): I12, four possible lymph nodes; I13, five possible lymph nodes; I14, two possible lymph nodes; I15, two possible lymph nodes; I16, one lymph node bisected. [REDACTED]

(J) CENTRAL COMPARTMENT DISSECTION - Received is an irregular piece of fibroadipose tissue (7.0 x 4.5 x 0.7 cm). Within the adipose tissue is an irregular fragment of bone (2.1 x 1.3 x 0.5 cm). Immediately adjacent to the bone is a cystic structure filled with chalky material (1.5 x 1.1 x 0.5 cm). One possible lymph node is identified within the fibroadipose tissue (0.6 x 0.3 x 0.2 cm).

SECTION CODE: J1, J2, cystic structure, serially sectioned, entirely submitted; J3, one possible lymph node; J4, section of bone adjacent to cystic structure for decalcification. [REDACTED]

(K) PROXIMAL V3 RIGHT - A 0.8 x 0.4 x 0.3 cm tan-red tissue fragment. Submitted in toto for frozen section in K. [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(L) RIGHT MANDIBLE MARGIN - A 0.6 x 0.4 x 0.2 cm aggregate of red-tan tissue and bone. Touch preparations are made for intraoperative assessment. The remainder of the specimen is submitted entirely in L for decalcification. [REDACTED]

*TP/DX: BONE MARROW CELLS, NO TUMOR PRESENT. [REDACTED]

(M) LEFT MANDIBLE MARGIN - A 0.4 x 0.4 x 0.2 cm aggregate of soft pink-tan tissue and bony fragments. Touch preparations are made for intraoperative evaluation, and the remainder of the tissue is submitted entirely in M for decalcification. [REDACTED]

*TP/DX: BONE MARROW CELLS, NO TUMOR PRESENT. [REDACTED]

(N) RIGHT TONGUE MARGIN - A 2.5 x 0.3 x 0.2 cm tan-pink tissue fragment. Submitted in toto for frozen section in N. [REDACTED]

*FS/DX: SQUAMOUS CARCINOMA IN SITU. [REDACTED]

(O) LEFT TONGUE MARGIN - A 2.2 x 0.4 x 0.2 cm tan-pink tissue fragment. Submitted in toto for frozen section in O. [REDACTED]

[page 4 of 5]
[REDACTED]

*FS/DX: SQUAMOUS CARCINOMA IN SITU. [REDACTED]
(P) LEFT BASE OF TONGUE - A 1.0 x 0.3 x 0.2 cm tan-pink tissue fragment. Submitted in toto for frozen section in P. [REDACTED]
*FS/DX: SQUAMOUS CARCINOMA IN SITU. [REDACTED]
(Q) RIGHT BASE OF TONGUE - A 1.5 x 1.0 x 0.5 cm tan-pink tissue fragment. Submitted in toto for frozen section in Q. [REDACTED]
*FS/DX: SQUAMOUS CARCINOMA IN SITU. [REDACTED]
(R) LEFT LEVEL II "B" - Received is a 1.2 x 1.2 x 0.7 cm fragment of tan-yellow nodular tissue. Specimen is bisected and submitted entirely in cassette R [REDACTED]
(S) COMPOSITE RESECTION, ANTERIOR FLOOR OF MOUTH, MANDIBLE - Received is an 8.0 x 4.5 x 6.0 cm portion of mandible containing three lower incisors, located in the middle of the anterior/middle portion of the mandible, is an edentulous area of tan-pink bosselated mucosa (4.0 x 3.0 x 2.0 cm) overlying a tan-white firm tumor (1.5 x 2.0 x 2.0 cm) that erodes inferiorly into the mandible. Multiple tan-pink lymph nodes are present in the submental and submandibular areas, ranging in size from 0.7 to 1.5 cm in greatest dimension. The submandibular gland (3.0 x 2.0 x 2.0 cm) is tan-yellow and appears uninvolved.
SECTION CODE: S1-S4, representative sections of dysplastic mucosa; S5-S12, representative sections of tumor; S13, submental lymph node; S14, representative sections of submandibular gland; S15, S16, multiple submandibular lymph nodes, each intact. The specimen is sent to the Bone Lab for decalcification and further processing. [REDACTED]
(T) RIGHT LEVEL IV - Received is an irregular piece of fibroadipose tissue (3.5 x 2.5 x 0.9 cm). Six possible lymph nodes are identified (ranging from 0.2 to 0.6 cm in greatest dimension).
SECTION CODE: T1, T2, two lymph nodes each; T3, one lymph node bisected; T4, three possible lymph nodes.
(U) TEETH - Received are two intact teeth (1.5 x 0.6 x 0.3 cm and 2.0 x 1.0 x 0.9 cm). The smaller tooth has a metallic filling. The larger tooth has a metallic crown and is attached at the crown to a fragment of another tooth (0.7 x 0.6 x 0.5 cm). Also present in the container is a fragment of a metallic cap (0.6 x 0.6 x 0.4 cm). The specimen is for gross examination only.
[REDACTED]

CLINICAL HISTORY

None given.

SNOMED CODES

[REDACTED]

[REDACTED]

[page 5 of 5]
ADDENDUM

This modified report is being issued to report the results of decalcification.

COMMENT

Sections of the mandible show invasion of bone by squamous carcinoma. Margins are free of tumor.

Source: NCI Genomic Data Commons file 1b39a3a4-cf0c-4614-b067-d3542c279503 (TCGA-CV-7235.600597E6-0BE0-4200-85CE-F8CD64CED7F4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).